Somatic mutation profile of tumor specimen 6d34d499-167e-42aa-9790-316fca (aliquot 6d34d499-167e-42aa-9790-316fca_D6_1) from CPTAC case 11BR043, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 36.6 years (13,352 days).
Specimen 6d34d499-167e-42aa-9790-316fca: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b68f54c0-7497-4912-8cb9-6a121cce32b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a1338e3d-598a-45b5-838f-9b6206 (Blood Derived Normal), aliquot a1338e3d-598a-45b5-838f-9b6206_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c3e4b21-a70d-4632-aa13-a3c367fb316b

The open-access MAF lists 108 somatic variants for this specimen: 72 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 24, Intron 6, Frame Shift Del 3, RNA 2, Splice Site 2, 3'UTR 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMCX2 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs782619057; called by muse, mutect2, varscan2
- CCDC82 | c.393T>G p.S131R | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as rs1315965562; called by muse, mutect2
- FLNB | c.5934C>G p.I1978M | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1280047807; called by muse, mutect2, varscan2
- GABRA5 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 55/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59477919; called by muse, mutect2, varscan2
- HSPA1B | c.63C>G p.F21L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs750593341; called by muse, mutect2
- KIF13A | c.2659A>G p.N887D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV52445029; called by muse, mutect2, varscan2
- LAMA1 | c.6931G>C p.D2311H | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101056592, COSV101056983; called by muse, mutect2
- OR4C12 | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV58860838; called by muse, mutect2, varscan2
- PLAG1 | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 19/585 reads (3%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.981); catalogued as COSV100388144; called by muse, mutect2
- RASGRF1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs967273029, COSV69179491; called by muse, mutect2, varscan2
- RGPD1 | c.3859_3862del p.K1288Lfs*5 (on ENST00000409776; = p.K1296Lfs*5 on NM_001024457.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 132/404 reads (33%) | catalogued as rs1182228455; called by pindel, varscan2
- SETD1B | c.4496C>T p.P1499L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1398412324; called by muse, mutect2, varscan2
- SLC12A4 | c.2667C>G p.I889M | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.434); catalogued as COSV50453821; called by muse, mutect2
- SNAP91 | c.657C>G p.L219= | Splice Region (SNP) | VAF 27/107 reads (25%) | catalogued as COSV52127538; called by muse, mutect2, varscan2
- STKLD1 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs782669062, COSV64311803; called by muse, mutect2, varscan2
- TAS1R2 | c.2054T>C p.I685T | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs764599825; called by muse, mutect2, varscan2
- VCAN | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427559; called by muse, mutect2
- ZBED5 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 86/278 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs913704250; called by muse, mutect2, varscan2
- ZNF462 | c.6622C>T p.R2208C | Missense Mutation (SNP) | VAF 26/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748283457, COSV52949996; called by muse, mutect2
- ABCC9 | c.1505T>A p.I502N | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AGAP3 | c.646C>T p.R216C (on ENST00000622464; = p.R252C on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AGER | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANK2 | c.7021A>T p.T2341S | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.009); called by muse, mutect2
- ANKRD20A1 | c.1459G>C p.E487Q | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.094); called by muse, varscan2
- ARAP3 | c.3053A>T p.D1018V | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ATAD2B | c.2551_2552insA p.F851Yfs*21 | Frame Shift Ins (INS) | VAF 28/98 reads (29%) | called by mutect2, pindel, varscan2
- ATP10B | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2
- C3orf20 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CBFA2T3 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CCDC141 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC168 | c.2738A>T p.E913V | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CCDC175 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- CCR5 | c.937C>G p.Q313E | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- CDC42BPB | c.11A>T p.K4M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- CDKN1B | c.295_305del p.C99Gfs*22 | Frame Shift Del (DEL) | VAF 30/192 reads (16%) | called by mutect2, varscan2
- COL20A1 | c.2695C>T p.H899Y | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2
- COL21A1 | c.50A>T p.Q17L | Missense Mutation (SNP) | VAF 10/259 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.056); called by muse, mutect2
- CYBA | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CYP7A1 | c.280T>G p.Y94D | Missense Mutation (SNP) | VAF 54/560 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.193); called by muse, mutect2
- DNAH14 | c.1828A>G p.T610A (on ENST00000445597; = p.T639A on NM_001367479.1) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2
- DNAH9 | c.12479G>C p.G4160A | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- DNAI2 | c.1038C>A p.N346K | Missense Mutation (SNP) | VAF 42/386 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- FLOT2 | c.94T>G p.W32G | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- IGFBPL1 | c.815del p.P272Qfs*20 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- LEFTY1 | c.157A>T p.I53F | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- LRBA | c.8011T>G p.W2671G | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRRC8E | c.304A>C p.I102L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2
- LZTS1 | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC5AC | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 87/251 reads (35%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- NBPF1 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- NUP160 | c.3848+1G>C p.X1283_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- OR52N4 | c.862C>G p.P288A | Missense Mutation (SNP) | VAF 34/318 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- PARP9 | c.1217T>A p.L406* | Nonsense Mutation (SNP) | VAF 19/400 reads (5%) | called by muse, mutect2
- PCDH15 | c.5581T>C p.S1861P | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- PCDHB11 | c.879A>T p.E293D | Missense Mutation (SNP) | VAF 77/579 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PCNT | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PPP2R2A | c.635T>C p.F212S | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RABL6 | c.2176T>C p.Y726H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- RFPL4AL1 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, varscan2
- RHBDD2 | c.964G>C p.A322P | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- RHBDD2 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); called by muse, mutect2
- RRP12 | c.783C>G p.C261W | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SAMD14 | c.16C>A p.L6I | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SCGB2A2 | c.243+2T>C p.X81_splice | Splice Site (SNP) | VAF 25/274 reads (9%) | called by muse, mutect2
- SLC22A16 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.278); called by muse, mutect2
- SNRPN | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SYT13 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.49); called by muse, mutect2
- TAS2R39 | c.926T>G p.I309S | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- TYRO3 | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2
- WRAP53 | c.365A>T p.E122V | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZHX1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF878 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 40/206 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADGRL2 | c.621A>T p.V207= | Silent (SNP) | VAF 23/295 reads (8%) | called by muse, mutect2
- APBA2 | c.1872C>A p.T624= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as rs1373490527, COSV67105125; called by muse, mutect2
- ATP10B | c.2790A>G p.R930= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- CLDN4 | c.576T>A p.P192= | Silent (SNP) | VAF 25/103 reads (24%) | called by muse, mutect2, varscan2
- CNTN2 | c.2349C>A p.P783= | Silent (SNP) | VAF 24/568 reads (4%) | catalogued as COSV100085441; called by muse, mutect2
- DNAJC6 | c.1308G>T p.S436= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV54775349, COSV99674321; called by muse, mutect2, varscan2
- DRD5 | c.690G>C p.S230= | Silent (SNP) | VAF 47/191 reads (25%) | catalogued as COSV58577842; called by muse, mutect2, varscan2
- EMCN | c.24T>A p.I8= | Silent (SNP) | VAF 27/171 reads (16%) | called by muse, mutect2, varscan2
- GRIA3 | c.42G>A p.A14= | Silent (SNP) | VAF 98/353 reads (28%) | catalogued as rs937720275; called by muse, mutect2, varscan2
- GRM1 | c.1959T>C p.T653= | Silent (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- GSTK1 | c.363G>A p.L121= | Silent (SNP) | VAF 33/207 reads (16%) | catalogued as rs575868481; called by muse, mutect2, varscan2
- HYDIN | c.5709C>T p.Y1903= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs367747312; called by muse, mutect2, varscan2
- MYCBPAP | c.1887C>T p.H629= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as rs766330950, COSV100088569; called by muse, mutect2
- NOP53 | c.901C>T p.L301= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- NYNRIN | c.2604G>A p.Q868= | Silent (SNP) | VAF 18/236 reads (8%) | called by muse, mutect2
- OR8B12 | c.51C>A p.T17= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV60911560; called by muse, mutect2, varscan2
- PCLO | c.297C>T p.P99= | Silent (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- PHACTR3 | c.921G>A p.Q307= | Silent (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- POLR1A | c.3924A>G p.K1308= | Silent (SNP) | VAF 10/210 reads (5%) | called by muse, mutect2
- PREX2 | c.3681C>T p.S1227= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as COSV99906247; called by muse, mutect2, varscan2
- PSEN1 | c.1056C>T p.R352= | Silent (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- PTCD1 | c.1320C>A p.V440= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs1380220935, COSV99464586; called by muse, mutect2, varscan2
- SDK1 | c.2679G>A p.P893= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs372139018, COSV67363964; called by muse, mutect2, varscan2
- TSKS | c.1527C>T p.H509= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs750484116, COSV99882934; called by muse, mutect2
- ABCA3 | c.*12T>A | 3'UTR (SNP) | VAF 8/254 reads (3%) | called by muse, mutect2
- ASPH | c.323-11679C>A | Intron (SNP) | VAF 22/520 reads (4%) | called by muse, mutect2
- ATP6AP1L | n.1875G>A | RNA (SNP) | VAF 20/358 reads (6%) | catalogued as rs1011165451; called by muse, mutect2
- FAM157A | n.27G>T | RNA (SNP) | VAF 35/275 reads (13%) | called by muse, mutect2, varscan2
- FAT1 | c.13139-1472G>C | Intron (SNP) | VAF 8/222 reads (4%) | called by muse, mutect2
- HPS4 | c.-34C>A | 5'UTR (SNP) | VAF 29/139 reads (21%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378168 C>A | 5'Flank (SNP) | VAF 24/236 reads (10%) | called by muse, mutect2
- MPRIP | c.2163+4469C>T | Intron (SNP) | VAF 16/134 reads (12%) | catalogued as rs201843718, COSV57926470; called by muse, mutect2, varscan2
- NRXN1 | c.3365-110170G>T | Intron (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- RAD51 | c.*4A>C | 3'UTR (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- SEC31B | c.2472+81A>T | Intron (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- VSIG1 | c.213+3290A>G | Intron (SNP) | VAF 11/178 reads (6%) | called by muse, mutect2
